Gene-level copy-number profile of tumor specimen TCGA-YB-A89D-01A from TCGA case TCGA-YB-A89D, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.7 years (21,792 days).
Specimen TCGA-YB-A89D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.9047c058-73fe-42a9-a5fd-ad1a1b6d58d2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YB-A89D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-YB-A89D-01A|TCGA-YB-A89D-11A); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/363e7a54-9be4-47b6-aa92-95e299b34e94

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 10,308; copy number 2: 48,852; copy number 3: 611; copy number 4: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YB-A89D-01A-12D-A36N-01): tumor purity 0.25, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,978. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
